Surgical pathology report (de-identified scan), TCGA case TCGA-19-5958, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5958-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

TCGA-19-5958

A. RIGHT PARIETAL NEOPLASM, BIOPSY:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

B. RIGHT PARIETAL TUMOR, EXCISION:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

C. INFERIOR WHITE MATTER, EXCISION:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Note: There is microvascular proliferation and coagulative tumor necrosis.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A: Microscopic: Glioblastoma.

Clinical History:

Right groin tumor

Specimens Submitted As:

A: RIGHT PARIETAL NEOPLASM

B: RIGHT PARIETAL TUMOR

C: INFERIOR WHITE MATTER

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and hospital number, is a 0.6 x 0.3 x 0.3 cm aggregate of soft, tan-white tissue. Touch imprint is performed. A portion of the specimen is submitted for frozen section. The specimen is submitted entirely in two cassettes.

B: Received fresh, is fixed in formalin, labeled with the patient's name and number, and "A-right parietal tumor", are multiple irregular, tan-brown, soft cerebriform tissue fragments measuring in aggregate 5.8 x 3.6 x 1.9 cm. Representative sections are submitted in three cassettes.

C: Received fresh, post fixed in formalin, labeled with the patient's name and number, and "B-inferior white matter", are multiple irregular, opaque white to pink-tan, soft, cerebriform tissue fragments measuring in aggregate 4.2 x 4.2 x 1.0 cm. Representative sections are submitted in three cassettes.

Summary of Cassettes:

A 1FS representative tissue
2 specimen submitted entirely

Source: NCI Genomic Data Commons file ecb9afe1-d934-4ea7-8341-2ae4be1c3e00 (TCGA-19-5958.AC50E8A3-BCA7-422E-937E-5521F9BFA399.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).